Gene-level copy-number profile of tumor specimen TCGA-DU-A5TY-01A from TCGA case TCGA-DU-A5TY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 46.4 years (16,945 days).
Specimen TCGA-DU-A5TY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.be17c1f3-df4b-4a47-b4b3-c923876c4ad2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-A5TY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cef731fa-e933-4e57-a7dc-8ee5e1ffa71b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,056; copy number 3: 2,335; copy number 4: 45,055; copy number 5: 1,312; copy number 6: 5,346; copy number 7: 383; copy number 8: 7; copy number 9: 208; copy number 10: 105; copy number 11: 125; copy number 12: 39; copy number 13: 52; copy number 14: 28; copy number 15: 27; copy number 16: 65; copy number 18: 111; copy number 19: 28; copy number 20: 7; copy number 21: 17; copy number 23: 31; copy number 24: 25; copy number 25: 30; copy number 26: 10; copy number 28: 17; copy number 29: 79; copy number 30: 37; copy number 31: 19; copy number 33: 10; copy number 35: 69; copy number 38: 10; copy number 39: 90; copy number 40: 1; copy number 41: 1; copy number 46: 9; copy number 49: 14; copy number 51: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-A5TY-01A-11D-A288-01): tumor purity 0.57, ploidy 4.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,326 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:14,985,378–36,453,791, 387 genes, copy number 10–49 (within-gene range 6–49) (broad region; genes not listed).
- chr7:39,888,375–75,416,787, 699 genes, copy number 9–51 (broad region; genes not listed).
- chr12:21,536,107–25,814,171, 64 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr12:57,459,785–57,586,633, 10 genes, copy number 38 (within-gene range 3–38): GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A.
- chr12:57,723,761–57,742,157, 1 gene, copy number 31 (within-gene range 3–31): AGAP2.
- chr12:57,738,013–57,896,846, 18 genes, copy number 31: TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr12:63,844,700–64,162,217, 1 gene, copy number 21 (within-gene range 3–21): SRGAP1.
- chr12:64,032,412–64,452,901, 16 genes, copy number 21: AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3.
- chr12:64,654,060–65,966,291, 30 genes, copy number 25: AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:66,189,195–66,343,643, 7 genes, copy number 30 (within-gene range 6–30): IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB.
- chr12:67,265,842–70,920,738, 83 genes, copy number 19–46 (broad region; genes not listed).
- chr12:71,609,599–71,835,396, 9 genes, copy number 33 (within-gene range 2–33): ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2.
- chr12:71,849,228–71,850,428, 1 gene, copy number 33: MRS2P2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
